Somatic mutation profile of tumor specimen TARGET-20-PARNIH-09A (aliquot TARGET-20-PARNIH-09A-01D) from TARGET case TARGET-20-PARNIH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.2 years (5,180 days).
Specimen TARGET-20-PARNIH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8d03d5c-a630-4172-ba34-b2c4a304ca2f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARNIH-14A (Bone Marrow Normal), aliquot TARGET-20-PARNIH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a36ead49-21e7-4a27-b105-6303732f4b21

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 51/127 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT5B | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 70/160 reads (44%) | called by muse, mutect2, varscan2
